Gene-level copy-number profile of tumor specimen TCGA-AF-6655-01A from TCGA case TCGA-AF-6655, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 66.9 years (24,417 days).
Specimen TCGA-AF-6655-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.399fde46-9740-4ff9-a0ab-153e200d2b6e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AF-6655-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/302493c7-a31e-41f9-a78a-3c78dc0ba98b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 4,091; copy number 4: 33,681; copy number 5: 7,528; copy number 6: 11,662; copy number 8: 1; copy number 9: 112; copy number 10: 1,457; copy number 11: 1,280.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AF-6655-01A-11D-1825-01): tumor purity 0.62, ploidy 2.44, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,849 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:64,515,654–74,136,892, 112 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr8:115,950,511–116,325,062, 1 gene, copy number 11 (within-gene range 6–11): LINC00536.
- chr8:116,289,622–145,066,685, 503 genes, copy number 11 (broad region; genes not listed).
- chr9:14,475–43,045,120, 776 genes, copy number 11 (broad region; genes not listed).
- chr20:87,250–16,053,197, 297 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr20:15,892,355–64,313,132, 1,160 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
